Somatic mutation profile of tumor specimen MP2PRT-PARLAF-TMP1-A (aliquot MP2PRT-PARLAF-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARLAF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,449 days).
Specimen MP2PRT-PARLAF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9296c23b-8409-43b4-9963-88a94af4176c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARLAF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARLAF-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6a112d2-2af1-45a0-b7f0-d66f00d8ddba

The open-access MAF lists 31 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 23, Silent 7, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 54/392 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3595G>C p.D1199H (on ENST00000404938 / NM_001163941.2; = p.D754H on NM_178559.6) | Missense Mutation (SNP) | VAF 15/334 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV51724374; called by muse, mutect2
- CHAT | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 214/530 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1306112783, CM105868, COSV60321866, COSV60328063; called by muse, varscan2
- CYLC1 | c.1580C>G p.S527C | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV100254856; called by muse, mutect2
- DHTKD1 | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 70/495 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs1253117210; called by muse, mutect2, varscan2
- GALNTL6 | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 26/519 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV104438898; called by muse, mutect2
- H2BC6 | c.204C>G p.N68K | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.497); catalogued as rs1020115294; called by muse, varscan2
- INTS5 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 72/630 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV57953001; called by muse, varscan2
- LCLAT1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 18/619 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335871088; called by muse, mutect2
- MTNR1B | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 313/847 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs369464202, CM121590; called by muse, mutect2, varscan2
- PCDH9 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 86/440 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as COSV60531552; called by muse, mutect2, varscan2
- SLC9B2 | c.528G>C p.L176F | Missense Mutation (SNP) | VAF 32/613 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60021857; called by muse, mutect2
- WDR13 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 67/386 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV99489153; called by muse, mutect2, varscan2
- ADAM22 | c.2491C>G p.R831G | Missense Mutation (SNP) | VAF 76/382 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALMS1 | c.5182G>C p.D1728H | Missense Mutation (SNP) | VAF 53/628 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 102/989 reads (10%) | called by pindel, varscan2
- DACH2 | c.1606G>C p.E536Q | Missense Mutation (SNP) | VAF 55/374 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNU1 | c.1459T>G p.C487G | Missense Mutation (SNP) | VAF 180/491 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PLA2R1 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 98/468 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, varscan2
- PLCE1 | c.4319G>T p.C1440F | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POPDC3 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 106/516 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RND2 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 88/795 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, varscan2
- SCLT1 | c.1894G>C p.E632Q | Missense Mutation (SNP) | VAF 33/405 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- UGGT2 | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- CHD5 | c.2415G>A p.G805= | Silent (SNP) | VAF 96/380 reads (25%) | catalogued as COSV52414309; called by muse, varscan2
- CHGB | c.777C>T p.S259= | Silent (SNP) | VAF 230/656 reads (35%) | called by muse, varscan2
- COL3A1 | c.1731C>T p.V577= | Silent (SNP) | VAF 74/390 reads (19%) | called by muse, mutect2, varscan2
- HAND2 | c.225G>A p.L75= | Silent (SNP) | VAF 112/962 reads (12%) | called by muse, varscan2
- HCN1 | c.1692T>C p.L564= | Silent (SNP) | VAF 176/487 reads (36%) | called by muse, mutect2, varscan2
- QRFPR | c.9G>A p.A3= | Silent (SNP) | VAF 73/475 reads (15%) | called by muse, mutect2, varscan2
- UHRF1 | c.1131G>A p.L377= (on ENST00000612630 / NM_001290050.1; = p.L390= on NM_013282.4) | Silent (SNP) | VAF 97/508 reads (19%) | catalogued as rs542736227; called by muse, mutect2, varscan2
